Gene-level copy-number profile of tumor specimen C3L-07144-01 from CPTAC case C3L-07144, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.3 years (24,956 days).
Specimen C3L-07144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 620faac3-d314-4497-9e99-029baa0ae4c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07144-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/d5a7ebf1-322f-4f2e-9788-0e447fd67b64

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 556; copy number 1: 33; copy number 2: 1,019; copy number 3: 2,940; copy number 4: 27,373; copy number 5: 3,783; copy number 6: 17,411; copy number 7: 885; copy number 8: 3,742; copy number 9: 215; copy number 10: 89; copy number 11: 687; copy number 12: 10; copy number 13: 6; copy number 16: 1; copy number 22: 30; copy number 35: 27; copy number 36: 7; copy number 37: 13; copy number 47: 1; copy number 62: 14; copy number 129: 10; copy number 149: 5; copy number 152: 2; copy number 154: 7; copy number 155: 6; copy number 156: 6; copy number 157: 6; copy number 167: 4.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,048,919–8,049,267, 1 gene: AC105233.1.
- chr8:8,086,022–8,096,726, 3 genes: AC105233.2, MIR548I3, RPS3AP31.
- chr13:48,303,744–48,599,436, 9 genes (within-gene range 0–11): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1.
- chr15:21,911,559–22,185,402, 18 genes (within-gene range 0–4): ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8.
- chr17:11,953,889–12,143,830, 7 genes (within-gene range 0–2): AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.
- chr19:21,722,771–21,852,125, 6 genes: ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,083 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–686,673, 41 genes, copy number 10–13: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16.
- chr9:33,441,156–34,311,371, 47 genes, copy number 12–37: AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P.
- chr13:18,467,172–46,211,871, 542 genes, copy number 9–11 (broad region; genes not listed).
- chr13:48,570,639–52,587,095, 99 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr13:52,600,042–73,995,056, 165 genes, copy number 9–11 (broad region; genes not listed).
- chr13:83,877,205–93,227,317, 78 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr14:23,969,874–24,051,377, 2 genes, copy number 11 (within-gene range 5–11): DHRS4L2, AL136419.1.
- chr16:11,359,845–11,527,245, 1 gene, copy number 35 (within-gene range 6–35): AC099489.1.
- chr16:11,465,260–11,828,845, 9 genes, copy number 35: AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr16:14,708,944–14,726,338, 1 gene, copy number 35: NPIPA3.
- chr16:14,748,066–15,139,339, 22 genes, copy number 35–37 (within-gene range 6–43): NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3.
- chr16:15,358,978–15,643,154, 8 genes, copy number 36–47: AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506.
- chr17:34,927,859–35,089,319, 5 genes, copy number 155 (within-gene range 6–155): CCT6B, AC022903.2, ZNF830, LIG3, RFFL.
- chr17:35,018,660–35,018,991, 1 gene, copy number 155 (within-gene range 6–155): AC004223.4.
- chr17:39,603,536–39,919,854, 16 genes, copy number 129–152: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB.
- chr17:41,029,697–41,098,142, 11 genes, copy number 154–167: KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8.
- chr17:41,186,944–41,309,253, 14 genes, copy number 62: KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1.
- chr17:41,549,606–41,865,423, 19 genes, copy number 10–157: LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11.
- chr19:22,925,377–22,925,547, 1 gene, copy number 10: AC022145.2.
- chr21:12,999,676–13,016,692, 1 gene, copy number 11: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
